CGCI case HTMCP-02-03-01002 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b94ca7cb-2c50-4154-8b79-13347911c9d9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 1,446 days (4.0 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.1 years (23,413 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,443 days (4.0 years).
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,443 days (4.0 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -2,751.

Other clinical attributes
- Day -2,751: Comorbidities: HIV/AIDS.
- Day -2,751: Risk factors: HIV/AIDS.
- Day 0: CD4 count: 299; Haart treatment indicator: No; HIV viral load: 927.
- Day 0: AIDS risk factors: Pneumonia, NOS.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 48; Tobacco smoking quit year: 2002.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01002-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01002-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Tumor status: Tumor free; Tobacco smoking age started: 15; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Performance status timing: Preoperative; Tobacco smoking history indicator: 4.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1996; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: No; Prior aids conditions: Pneumonia, recurrent.
- Primary pathology: Method initial path diagnosis: Tumor resection.
